Somatic mutation profile of tumor specimen TCGA-VS-A94Y-01A (aliquot TCGA-VS-A94Y-01A-11D-A387-09) from TCGA case TCGA-VS-A94Y, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 47.8 years (17,465 days).
Specimen TCGA-VS-A94Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8169090a-6cb2-4e0c-99bd-92b733883b07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A94Y-10A (Blood Derived Normal), aliquot TCGA-VS-A94Y-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c66e5c87-efbc-4937-944a-11ee2902ea02

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 31, Silent 17, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAH | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs62642939, CM071054, CM971133, COSV100187604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.401); catalogued as COSV101024034, COSV65534918; called by muse, mutect2, varscan2
- ANKRD24 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668200, COSV99516926; called by muse, mutect2, varscan2
- CADPS2 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV57366540; called by muse, mutect2, varscan2
- CCDC70 | c.291G>C p.W97C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99665300, COSV99665313; called by muse, mutect2, varscan2
- CILP2 | c.1136-1G>T p.X379_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99364300; called by muse, mutect2
- CNTNAP2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as rs756180841, COSV100662536, COSV62150589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS7A | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs151177416; called by muse, mutect2, varscan2
- DCC | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.155); catalogued as COSV101472307; called by muse, mutect2, varscan2
- DMTF1 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99991264; called by muse, mutect2, varscan2
- EFL1 | c.2705T>A p.F902Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99186337; called by muse, mutect2, varscan2
- GAL3ST3 | c.659A>C p.D220A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs780045661, COSV61748627, COSV61749042; called by muse, mutect2, varscan2
- JMJD1C | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV101232164; called by muse, mutect2, varscan2
- KIF1A | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs369842871; called by muse, mutect2, varscan2
- KRTAP4-12 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs545855586, COSV101224249; called by muse, mutect2, varscan2
- LAMA1 | c.3917C>T p.T1306M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs374697577; called by muse, mutect2, varscan2
- LYSMD1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99765854; called by muse, mutect2, varscan2
- MMRN2 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs148010690; called by muse, mutect2, varscan2
- MROH9 | c.245T>A p.V82E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100882682; called by mutect2, varscan2
- NEMF | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs996673326, COSV100027351; called by muse, mutect2, varscan2
- NMRK2 | c.165C>T p.D55= | Splice Region (SNP) | VAF 36/74 reads (49%) | catalogued as rs567450517, COSV99396233; called by muse, mutect2, varscan2
- NUDT13 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100624675; called by muse, mutect2, varscan2
- OR2T10 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs774622371, COSV100393579; called by muse, mutect2, varscan2
- PRUNE2 | c.5125G>T p.V1709F | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV100944204; called by muse, mutect2, varscan2
- PZP | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99735973; called by muse, mutect2, varscan2
- RPS9 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs780013236, COSV100256334; called by muse, mutect2, varscan2
- RYR3 | c.10025C>G p.S3342C (on ENST00000389232; = p.S3343C on NM_001036.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101211959; called by muse, mutect2, varscan2
- SETD2 | c.4108C>A p.P1370T | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1372739848, COSV100337941; called by muse, mutect2, varscan2
- SLC19A1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV60754761; called by muse, mutect2, varscan2
- SLC39A4 | c.1153C>A p.L385M (on ENST00000301305 / NM_001374839.1; = p.L360M on NM_017767.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99432971; called by muse, mutect2, varscan2
- SPATA31D1 | c.3116C>T p.S1039L | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1307885343, COSV100782456; called by muse, mutect2, varscan2
- TBXT | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV99752052; called by muse, mutect2, varscan2
- TMPRSS2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100151122; called by muse, mutect2, varscan2
- ZSCAN5A | c.1166G>C p.C389S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774911834, COSV99569703, COSV99570021; called by muse, mutect2, varscan2
- FAT1 | c.11737_11746del p.A3913Wfs*3 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- MKI67 | c.3165_3166del p.H1055Qfs*14 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by pindel, varscan2
- CADPS | c.2139C>T p.D713= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs142840753; called by muse, mutect2, varscan2
- EPC1 | c.1086A>G p.P362= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99552537; called by muse, mutect2, varscan2
- EXD3 | c.2136G>A p.K712= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100573394; called by muse, mutect2, varscan2
- FBLN2 | c.1101C>T p.L367= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs750825548, COSV99851348; called by muse, mutect2, varscan2
- FOXI1 | c.996C>T p.S332= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs559100797, COSV60389497; called by muse, mutect2, varscan2
- KLHL3 | c.270G>A p.K90= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100552878; called by muse, mutect2, varscan2
- KMT2D | c.9297C>T p.R3099= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs368160122; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA3 | c.3126C>T p.F1042= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100555476; called by muse, mutect2, varscan2
- LVRN | c.1815C>G p.T605= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100773317; called by muse, mutect2, varscan2
- NALCN | c.1131C>A p.L377= | Silent (SNP) | VAF 67/102 reads (66%) | catalogued as COSV99212889; called by muse, mutect2, varscan2
- OR2A5 | c.669G>A p.A223= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs771031861, COSV68738523; called by muse, mutect2, varscan2
- OR52J3 | c.402C>T p.Y134= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs149427006, COSV66747934; called by muse, mutect2, varscan2
- SLC15A2 | c.1977C>T p.I659= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs780742792, COSV99815069; called by muse, mutect2, varscan2
- SLC4A1 | c.1824C>T p.F608= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs751967295, COSV99292966; called by muse, mutect2, varscan2
- TRBV19 | c.117C>T p.T39= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- UNC5B | c.1249C>T p.L417= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100100176; called by muse, mutect2, varscan2
- ZNF281 | c.1668C>T p.N556= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs371671509; called by muse, mutect2, varscan2
